Somatic mutation profile of tumor specimen TCGA-AB-2891-03A (aliquot TCGA-AB-2891-03A-01W-0733-08) from TCGA case TCGA-AB-2891, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 42.2 years (15,400 days).
Specimen TCGA-AB-2891-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 058020fc-d920-4f6f-8a68-fc1b724075ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2891-11A (Solid Tissue Normal), aliquot TCGA-AB-2891-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9022c7ce-1981-4ed5-94ab-be0d6c1ea34b

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BSN | c.11660A>G p.Q3887R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV56519546; called by mutect2, varscan2
- CFAP300 | c.785G>A p.G262D | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71570818; called by muse, varscan2
- CLPX | c.593A>G p.Y198C | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV55644784; called by muse, mutect2, varscan2
- DNMT3A | c.1851+2T>C p.X617_splice | Splice Site (SNP) | VAF 11/33 reads (33%) | catalogued as rs757785566, COSV53056469; called by muse, mutect2, varscan2
- EPHA10 | c.2161A>G p.I721V | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs913419992, COSV57624456; called by muse, mutect2, varscan2
- TMPRSS7 | c.2312C>T p.S771F (on ENST00000452346; = p.S645F on NM_001042575.2) | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs1234455284, COSV101340076; called by muse, mutect2
